Somatic mutation profile of tumor specimen C3L-06952-54 (aliquot CPT0395410002) from CPTAC case C3L-06952, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 86.5 years (31,578 days).
Specimen C3L-06952-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2828f505-fa2b-48c6-9da9-e2d8132a4dd5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06952-51 (Buccal Cell Normal), aliquot CPT0395510002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/799657e2-3c2d-47cd-a817-176272a9dca7

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIF1 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- RNF111 | c.46G>A p.V16M | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.265); called by muse, varscan2
- TET2 | c.1219del p.S407Lfs*20 | Frame Shift Del (DEL) | VAF 54/125 reads (43%) | called by mutect2, pindel, varscan2
- TRPM1 | c.925C>A p.Q309K | Missense Mutation (SNP) | VAF 11/302 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); called by muse, mutect2
- DDX60L | c.4278G>A p.L1426= | Silent (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
